Somatic mutation profile of tumor specimen ALCH-AESN-TTP1-A (aliquot ALCH-AESN-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AESN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.5 years (21,722 days).
Specimen ALCH-AESN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 849799cc-cdc8-48cf-9e14-2878824ee87d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AESN-NB1-A (Blood Derived Normal), aliquot ALCH-AESN-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/519862a0-9c33-432f-af9a-51855179abca

The open-access MAF lists 364 somatic variants for this specimen: 232 protein-altering or splice-affecting, 88 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 88, Intron 23, Nonsense Mutation 19, RNA 9, 3'UTR 6, Splice Site 6, Frame Shift Del 5, 5'Flank 3, Splice Region 3, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 121/381 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, mutect2, varscan2
- UBE3A | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs587783146, COSV51672188; ClinVar: likely pathogenic; called by muse, mutect2
- ACSM4 | c.800G>T p.W267L | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV68068786; called by muse, mutect2, varscan2
- ACSM4 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68068836, COSV68069144; called by muse, mutect2, varscan2
- ANKRD30B | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV100746889; called by muse, mutect2
- ANTXRL | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as rs1283364345; called by muse, mutect2
- ANXA6 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905891; called by muse, mutect2
- ASXL3 | c.4633G>T p.A1545S | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs1158086019; called by muse, mutect2
- BTBD11 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99777132; called by mutect2, varscan2
- BTBD3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV54780819; called by muse, mutect2
- CAPN1 | c.1199G>T p.R400L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV54199654; called by muse, mutect2, varscan2
- CFTR | c.4328C>T p.P1443L | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV99134637; called by muse, mutect2
- CNGB3 | c.129+1G>T p.X43_splice | Splice Site (SNP) | VAF 41/295 reads (14%) | catalogued as CS136016; called by muse, mutect2, varscan2
- CNTNAP4 | c.2933G>C p.R978T | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV56667915; called by muse, mutect2, varscan2
- COL4A6 | c.1042G>T p.V348F | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV57864437; called by muse, mutect2
- CRB1 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 45/327 reads (14%) | catalogued as COSV66340053; called by muse, mutect2, varscan2
- CXorf66 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV100983826, COSV100983949; called by muse, mutect2
- DCAF4L2 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100150443; called by muse, mutect2, varscan2
- DMD | c.2588del p.P863Qfs*8 | Frame Shift Del (DEL) | VAF 28/270 reads (10%) | catalogued as CD098809; called by mutect2, pindel, varscan2
- EYS | c.1612G>T p.G538* | Nonsense Mutation (SNP) | VAF 32/264 reads (12%) | catalogued as rs780233995; called by muse, mutect2, varscan2
- FBN1 | c.5284G>T p.G1762C | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM115510, COSV100355674; called by muse, mutect2
- FUT3 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs375070581; called by muse, varscan2
- GPATCH2L | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1205689588; called by muse, mutect2
- GPR173 | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV60234069, COSV60237023; called by muse, mutect2, varscan2
- HERC6 | c.2578A>G p.I860V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs763244765; called by muse, mutect2, varscan2
- IGKV2D-24 | c.209G>T p.R70I | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1558923026; called by muse, mutect2
- IRGQ | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.104); catalogued as rs774828592; called by muse, mutect2, varscan2
- KCNU1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67759783; called by muse, mutect2
- KIAA1217 | c.5597G>T p.S1866I | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV56820592; called by muse, mutect2
- LRRC20 | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV62938497; called by muse, mutect2, varscan2
- MAG | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as rs745533880; called by muse, mutect2, varscan2
- MAGEA12 | c.272A>T p.E91V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63294298; called by muse, mutect2, varscan2
- MDN1 | c.5021A>T p.K1674M | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV65529019; called by muse, mutect2
- MEGF6 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as rs1292283552; called by muse, varscan2
- MYBPC2 | c.2707G>T p.A903S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV63093120; called by muse, mutect2, varscan2
- NAA25 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV55709214; called by muse, mutect2
- NBAS | c.6155G>T p.S2052I | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55738225; called by muse, mutect2
- NLRC4 | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV100707150; called by muse, mutect2
- NLRP11 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as COSV64085660; called by muse, mutect2, varscan2
- OPHN1 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62780318; called by muse, mutect2
- PCDH11X | c.1252C>A p.L418M | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV53491939; called by muse, mutect2
- PCDHB13 | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.099); catalogued as rs782079192; called by muse, mutect2
- PCLO | c.14201T>C p.V4734A | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296851043; called by muse, mutect2
- PLA2G4F | c.1814C>G p.S605W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.68); catalogued as rs149624289; called by muse, mutect2
- PLEKHH2 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV56761904; called by muse, mutect2, varscan2
- PRKCG | c.1738del p.R580Gfs*11 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | catalogued as COSV54724060; called by mutect2, pindel, varscan2
- PRKDC | c.8223G>T p.L2741F | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV58047931; called by muse, mutect2, varscan2
- PRPF38B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1399130954, COSV64223740; called by muse, mutect2, varscan2
- PTBP2 | c.685G>T p.A229S (on ENST00000426398 / NM_001300986.2; = p.A221S on NM_021190.4) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1410793808; called by muse, mutect2
- RAG1 | c.2894A>G p.E965G | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55024401; called by muse, mutect2
- RPGRIP1 | c.1355A>G p.H452R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs1436629419; called by muse, mutect2, varscan2
- SCN11A | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs1189990465; called by muse, mutect2
- SDK1 | c.3155G>T p.G1052V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67356658; called by muse, mutect2, varscan2
- SEMA6A | c.2657C>A p.A886D | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753365134, COSV99145527; called by muse, mutect2, varscan2
- SGSH | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs373624543; called by muse, mutect2
- SLC6A12 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV62886342; called by muse, mutect2, varscan2
- SLC8A1 | c.2405C>A p.A802E | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100245325; called by muse, mutect2
- SMARCA4 | c.4897G>T p.E1633* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100758187; called by muse, mutect2
- SMCO1 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV66877594; called by muse, mutect2, varscan2
- STAT3 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 14/396 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV52884372; called by muse, mutect2
- SYK | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV65324880; called by muse, mutect2
- TBR1 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.086); catalogued as COSV101271396; called by muse, mutect2, varscan2
- TKT | c.1468G>T p.G490* | Nonsense Mutation (SNP) | VAF 18/173 reads (10%) | catalogued as COSV56245965; called by muse, mutect2
- TMEM71 | c.598G>T p.G200* (on ENST00000523829 / NM_001382398.1; = p.G181* on NM_144649.3) | Nonsense Mutation (SNP) | VAF 14/100 reads (14%) | catalogued as COSV63456938; called by muse, varscan2
- TMPRSS15 | c.1607C>G p.T536R | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV53043597; called by muse, mutect2
- TP53 | c.1044G>T p.L348F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52730754, COSV52829880; called by mutect2, varscan2
- VWC2 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 8/129 reads (6%) | catalogued as COSV100514821; called by muse, mutect2
- WNK3 | c.3610C>A p.L1204M | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.832); catalogued as COSV63615298; called by muse, mutect2
- ZNF804A | c.2788G>T p.D930Y | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100166011; called by muse, mutect2
- ABCB1 | c.3217G>T p.G1073C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- ABCC8 | c.1014A>T p.T338= | Splice Region (SNP) | VAF 46/241 reads (19%) | called by muse, mutect2, varscan2
- ADAD1 | c.1192C>G p.Q398E | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2
- ADAMTS7 | c.3629G>T p.W1210L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADCY1 | c.3273del p.M1092Cfs*47 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- AP002512.3 | c.1244A>T p.Q415L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- APOE | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ARHGEF10 | c.762G>T p.M254I (on ENST00000398564; = p.M229I on NM_014629.4) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- ATP1B4 | c.591G>C p.M197I (on ENST00000218008 / NM_001142447.3; = p.M193I on NM_012069.5) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); called by muse, mutect2
- AWAT1 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- BCORL1 | c.3677G>A p.R1226H | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIRC6 | c.6633G>T p.Q2211H | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- BRWD3 | c.4552C>T p.P1518S | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); called by muse, mutect2
- BRWD3 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- CACNA1I | c.3866C>T p.A1289V | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- CCDC154 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2
- CCDC175 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CCDC59 | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC63 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.099); called by muse, mutect2
- CCL18 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCL23 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CD37 | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CEP72 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.817); called by muse, mutect2
- CLEC4E | c.337_338insT p.A113Vfs*21 | Frame Shift Ins (INS) | VAF 35/119 reads (29%) | called by mutect2, pindel, varscan2
- CLEC4G | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CLEC7A | c.475G>T p.D159Y (on ENST00000304084 / NM_197947.3; = p.D113Y on NM_022570.5) | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLSTN3 | c.1344C>G p.H448Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMTR1 | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL11A1 | c.4289C>A p.P1430Q | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- COL14A1 | c.5078-2A>T p.X1693_splice | Splice Site (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- COL27A1 | c.2485G>T p.G829C | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.47C>A p.T16N | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.055); called by muse, mutect2
- COL6A6 | c.1665G>T p.E555D | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL9A1 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPS1 | c.141C>A p.H47Q | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPXCR1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.021); called by muse, varscan2
- CRHBP | c.871G>T p.V291L | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CSF2RA | c.728A>T p.Y243F | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2
- DDX3X | c.753G>T p.R251S (on ENST00000399959; = p.R252S on NM_001356.5) | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.481); called by muse, mutect2
- DHRS11 | c.630C>A p.H210Q | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX58 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- DNAH5 | c.11084C>T p.T3695I | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DOK6 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2
- DQX1 | c.1604C>A p.A535D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DSC3 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- EFHC2 | c.1163A>T p.E388V | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.215); called by muse, mutect2
- FASN | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- FAT3 | c.3646C>A p.Q1216K | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAT3 | c.11374T>C p.C3792R | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCHSD2 | c.1631A>T p.D544V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2
- FCN2 | c.759C>A p.N253K | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- FLG | c.1108G>C p.A370P | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.946); called by muse, mutect2
- FMNL2 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.743); called by muse, mutect2
- FMR1 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.647); called by muse, mutect2
- FOXP2 | c.2015A>T p.H672L | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2
- GAB3 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- GABRG1 | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- GAD1 | c.1212C>G p.H404Q | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GALNTL6 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GAREM1 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GLIS3 | c.1664-1G>T p.X555_splice | Splice Site (SNP) | VAF 35/134 reads (26%) | called by muse, mutect2, varscan2
- GLRX3 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- GPR1 | c.643T>A p.Y215N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GPR87 | c.878A>T p.Y293F | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GPRASP2 | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 41/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A2 | c.919C>A p.Q307K | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HDAC6 | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- HGF | c.671A>G p.D224G | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2
- IGHV1-24 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- IL36G | c.40del p.A14Pfs*17 | Frame Shift Del (DEL) | VAF 27/236 reads (11%) | called by mutect2, pindel, varscan2
- IPO8 | c.1893G>T p.Q631H | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- IQGAP2 | c.4205A>T p.K1402M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ITGB1BP2 | c.469-1G>T p.X157_splice | Splice Site (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- KCNA4 | c.286C>A p.H96N | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH5 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- KDM5C | c.2241G>C p.L747= | Splice Region (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- KIAA0319L | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.319); called by muse, mutect2
- KIAA1109 | c.14008G>T p.G4670C | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIFC3 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); called by muse, mutect2
- KPRP | c.759C>A p.S253R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2
- KRT5 | c.488G>T p.R163M | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- KRTAP9-4 | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRRIQ4 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MAP7D1 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MAPRE2 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2
- MBD5 | c.2683G>T p.E895* | Nonsense Mutation (SNP) | VAF 20/359 reads (6%) | called by muse, mutect2
- MYF5 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- NEXMIF | c.2438G>T p.G813V | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKRF | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NOTCH4 | c.1494C>A p.H498Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- NPBWR1 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.686); called by mutect2, varscan2
- NRAP | c.2614C>A p.H872N (on ENST00000359988 / NM_001322945.2; = p.H837N on NM_006175.4) | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NRK | c.3031G>T p.G1011* | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- NT5DC3 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR10X1 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR2B11 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- OR2T33 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 17/247 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); called by muse, mutect2
- OR2T4 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.953); called by muse, mutect2
- OR2V1 | c.418A>T p.R140W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR4S2 | c.354T>A p.Y118* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- OTOF | c.2593G>C p.V865L (on ENST00000272371 / NM_194248.3; = p.V118L on NM_004802.4) | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- PCDH10 | c.2638C>A p.H880N | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.104); called by muse, mutect2
- PCDH11X | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 18/419 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PDGFA | c.613del p.R205Efs*4 | Frame Shift Del (DEL) | VAF 19/172 reads (11%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PIKFYVE | c.2191-1G>C p.X731_splice | Splice Site (SNP) | VAF 22/251 reads (9%) | called by muse, mutect2
- PLEKHD1 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLS3 | c.839A>T p.H280L | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- POLR1E | c.563G>A p.S188N (on ENST00000377792 / NM_001282766.1; = p.S126N on NM_022490.4) | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POMT1 | c.539+2T>A p.X180_splice | Splice Site (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- PQBP1 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM9 | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, varscan2
- PTGS1 | c.1123C>A p.R375S | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PTPRD | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by mutect2, varscan2
- PYGL | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.2692G>T p.G898C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM20 | c.809C>A p.T270K | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.127); called by muse, mutect2
- RFX4 | c.2103G>T p.M701I (on ENST00000392842 / NM_213594.3; = p.M607I on NM_032491.6) | Missense Mutation (SNP) | VAF 19/364 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2
- RIMS2 | c.1388G>C p.S463T (on ENST00000666250 / NM_001348490.2; = p.S271T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RNF130 | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO3 | c.1000C>A p.R334S | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RSKR | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- SCN11A | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2
- SGCD | c.710C>A p.A237D (on ENST00000435422 / NM_001128209.2; = p.A238D on NM_000337.5) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SH2D7 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SLC25A14 | c.700A>T p.T234S | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.145); called by muse, mutect2
- SLC27A6 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); called by muse, mutect2
- SP3 | c.1777A>G p.K593E | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- SPECC1 | c.3083A>G p.E1028G | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SSH2 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- STAG2 | c.3493G>T p.D1165Y | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- STARD5 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.89); called by mutect2, varscan2
- STYXL2 | c.1955C>A p.T652K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by mutect2, varscan2
- TAF1 | c.2340T>G p.N780K (on ENST00000373790 / NM_138923.4; = p.N801K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- TBC1D3B | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 33/358 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TCF4 | c.691A>T p.S231C | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- TEX11 | c.291A>G p.L97= (on ENST00000344304; = p.L82= on NM_031276.3) | Splice Region (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- TEX13C | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM132E | c.1630G>T p.V544L (on ENST00000321639; = p.V634L on NM_001304438.2) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM196 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- TMEM67 | c.2800G>T p.G934* | Nonsense Mutation (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 112/323 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- TNFSF11 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAV8-4 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, varscan2
- TRPC4 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- TSHZ3 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- TTC17 | c.1585A>G p.K529E | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- UGT3A2 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- ULK2 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- UNK | c.725A>G p.D242G | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UTS2B | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- VMA21 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- WDR38 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WFIKKN2 | c.1307G>T p.C436F | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WTAP | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZFPM2 | c.2189A>T p.Q730L | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZMYM2 | c.2815A>T p.S939C | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF292 | c.2773G>T p.A925S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF525 | c.903T>A p.C301* | Nonsense Mutation (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- ZNF676 | c.934C>T p.P312S (on ENST00000650058; = p.P280S on NM_001001411.3) | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ZNF804A | c.3175A>C p.N1059H | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2
- ADGRV1 | c.6330C>T p.I2110= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV101315727; called by muse, mutect2, varscan2
- ANKRD24 | c.2853C>T p.R951= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1299721900; called by muse, mutect2, varscan2
- BMP10 | c.399C>T p.S133= | Silent (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- BMPR1B | c.627G>A p.Q209= | Silent (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2
- BRSK1 | c.1431G>T p.T477= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV58669194; called by muse, mutect2
- CCDC168 | c.1701G>C p.P567= | Silent (SNP) | VAF 19/237 reads (8%) | called by muse, mutect2
- CCL18 | c.108C>A p.S36= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- CCL4 | c.240C>T p.S80= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- CLHC1 | c.714G>C p.L238= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2698C>A p.R900= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs375318010, COSV62157895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.1923T>A p.P641= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- CRACD | c.1800C>T p.G600= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs367553040, COSV99948699; called by muse, mutect2, varscan2
- DQX1 | c.1605C>A p.A535= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99283630; called by muse, mutect2, varscan2
- ERBB4 | c.216G>T p.R72= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- EXD3 | c.603G>T p.L201= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- FAT2 | c.3003C>G p.A1001= | Silent (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- FAT3 | c.13014C>T p.S4338= | Silent (SNP) | VAF 11/209 reads (5%) | called by muse, mutect2
- FDFT1 | c.183G>T p.L61= | Silent (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- FNDC7 | c.1965C>A p.A655= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- FRMD6 | c.330C>T p.H110= (on ENST00000344768 / NM_001267046.2; = p.H102= on NM_152330.4) | Silent (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- GGCX | c.309G>A p.L103= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- GRIA2 | c.549T>C p.I183= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as rs1252316201; called by muse, mutect2, varscan2
- GRIP1 | c.120G>A p.R40= | Silent (SNP) | VAF 24/406 reads (6%) | catalogued as rs1241842539; called by muse, mutect2
- HDAC8 | c.48G>T p.P16= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- HEPACAM | c.555G>A p.K185= | Silent (SNP) | VAF 10/229 reads (4%) | called by muse, mutect2
- HRNR | c.8253T>A p.S2751= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- JAG2 | c.1803A>T p.A601= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- JAK1 | c.1257C>G p.A419= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- LCT | c.3708G>A p.E1236= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1402951413; called by muse, mutect2, varscan2
- LSAMP | c.18C>A p.P6= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- LTBP2 | c.2103G>T p.V701= | Silent (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- MIB1 | c.2832T>C p.N944= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as rs1389159756; called by muse, mutect2
- MLLT6 | c.2880C>T p.T960= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs372462059; called by mutect2, varscan2
- MME | c.1701C>A p.A567= | Silent (SNP) | VAF 41/282 reads (15%) | catalogued as rs1451226996; called by muse, mutect2, varscan2
- MON1B | c.993C>T p.N331= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs1309438390; called by muse, mutect2, varscan2
- MPP1 | c.531C>A p.I177= | Silent (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- MTOR | c.5520C>T p.T1840= | Silent (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- MUC5AC | c.16524C>A p.A5508= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- MUSK | c.1455C>A p.S485= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- MX2 | c.996G>A p.E332= | Silent (SNP) | VAF 22/289 reads (8%) | called by muse, mutect2
- MYH6 | c.2364G>T p.T788= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV62453578; called by muse, mutect2, varscan2
- MYH8 | c.2787T>A p.A929= | Silent (SNP) | VAF 30/330 reads (9%) | called by muse, mutect2
- MYO15A | c.804C>T p.S268= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV52751804; called by mutect2, varscan2
- NGB | c.40C>A p.R14= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- NRXN3 | c.3177C>A p.A1059= (on ENST00000335750 / NM_001330195.2; = p.A686= on NM_004796.6) | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- ONECUT1 | c.1212C>T p.F404= | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as COSV59951382; called by muse, mutect2, varscan2
- OR10J3 | c.645C>A p.V215= | Silent (SNP) | VAF 24/326 reads (7%) | catalogued as rs1283481677; called by muse, mutect2
- OR13C8 | c.405C>T p.I135= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV100622935, COSV58610772; called by muse, mutect2
- OR2T10 | c.432G>A p.L144= | Silent (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- OR4A5 | c.369C>A p.A123= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- OXCT1 | c.759A>G p.A253= | Silent (SNP) | VAF 19/286 reads (7%) | called by muse, mutect2
- PATE2 | c.192C>T p.I64= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs749837252, COSV62069237; called by muse, mutect2, varscan2
- PCSK1 | c.1230G>A p.L410= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- PLXNA4 | c.3300C>T p.A1100= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs1307534084; called by muse, mutect2, varscan2
- PPFIA4 | c.1374G>T p.T458= | Silent (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- PRUNE2 | c.6015A>T p.L2005= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- PTPN14 | c.72G>T p.R24= | Silent (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- RBBP5 | c.879G>T p.T293= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV52704350; called by muse, mutect2, varscan2
- RCSD1 | c.804A>T p.S268= | Silent (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- RESF1 | c.1479T>C p.N493= | Silent (SNP) | VAF 16/345 reads (5%) | catalogued as rs1411773216; called by muse, mutect2
- RPA4 | c.504G>C p.L168= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as rs1388715702; called by muse, mutect2, varscan2
- RPRM | c.99G>T p.A33= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57988482; called by muse, mutect2, varscan2
- RSBN1 | c.526C>T p.L176= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1362034347; called by muse, mutect2, varscan2
- RTL9 | c.2424G>T p.T808= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV101511809; called by muse, mutect2, varscan2
- SLC17A8 | c.273G>T p.G91= | Silent (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2
- SNTG1 | c.1152C>A p.A384= | Silent (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- SNX15 | c.186G>T p.L62= | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, varscan2
- SNX18 | c.1593C>T p.N531= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as rs766762186; called by muse, mutect2, varscan2
- SPTA1 | c.3768C>T p.A1256= | Silent (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- STK3 | c.501G>T p.V167= | Silent (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- SYNE3 | c.2892G>C p.T964= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- TAP1 | c.801T>C p.F267= | Silent (SNP) | VAF 32/255 reads (13%) | called by muse, mutect2, varscan2
- TBC1D30 | c.1731T>C p.F577= (on ENST00000542120; = p.F414= on NM_015279.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/235 reads (3%) | called by muse, mutect2
- TBC1D8 | c.1431C>T p.S477= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- TEX13C | c.174G>T p.R58= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- TRIM48 | c.372G>A p.R124= | Silent (SNP) | VAF 13/271 reads (5%) | catalogued as COSV70161549; called by muse, mutect2
- TUB | c.789C>A p.I263= (on ENST00000299506 / NM_177972.3; = p.I318= on NM_003320.4) | Silent (SNP) | VAF 18/303 reads (6%) | called by muse, mutect2
- UGT1A9 | c.409T>C p.L137= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- UGT3A2 | c.489G>A p.V163= | Silent (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- URM1 | c.117G>T p.R39= | Silent (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- UTP20 | c.3531T>C p.D1177= | Silent (SNP) | VAF 26/172 reads (15%) | called by muse, mutect2, varscan2
- VPS37B | c.30C>T p.F10= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs769052349, COSV57362211; called by mutect2, varscan2
- VWF | c.5532C>A p.G1844= | Silent (SNP) | VAF 28/346 reads (8%) | catalogued as COSV54612857; called by muse, mutect2
- ZFHX4 | c.750C>A p.S250= | Silent (SNP) | VAF 16/147 reads (11%) | called by muse, mutect2, varscan2
- ZNF560 | c.2133C>A p.P711= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- ZNF681 | c.1674A>T p.G558= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs1041140569; called by muse, mutect2
- ZNF711 | c.363C>A p.T121= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as rs1220278471; called by muse, mutect2
- ZNF804B | c.645C>T p.H215= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- AC020637.1 | n.903C>T | RNA (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- AC027031.1 | n.203G>T | RNA (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- AC133561.1 | n.1921C>G | RNA (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1137C>A | RNA (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- ACTN2 | c.784-514A>T | Intron (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- AIRE | c.463+49C>A | Intron (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- AL353804.4 | chrX:73821238 C>A | 3'Flank (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- C3orf35 | chr3:37417416 G>T | 3'Flank (SNP) | VAF 19/176 reads (11%) | called by muse, mutect2, varscan2
- C9orf62 | n.314C>A | RNA (SNP) | VAF 4/31 reads (13%) | called by muse, varscan2
- COL4A5 | c.4803+17C>A | Intron (SNP) | VAF 18/235 reads (8%) | called by muse, mutect2
- CRACD | c.*546T>A | 3'UTR (SNP) | VAF 20/179 reads (11%) | catalogued as rs1218417527; called by muse, mutect2, varscan2
- EFHC1 | c.*170G>A | 3'UTR (SNP) | VAF 12/149 reads (8%) | called by muse, mutect2
- EYS | c.1766+2623G>A | Intron (SNP) | VAF 26/262 reads (10%) | catalogued as rs867776546, COSV60980320; called by muse, mutect2, varscan2
- FAM153CP | n.407G>T | RNA (SNP) | VAF 37/131 reads (28%) | catalogued as COSV67753201; called by muse, mutect2, varscan2
- FOLH1B | n.1918dup | RNA (INS) | VAF 23/167 reads (14%) | called by mutect2, pindel, varscan2
- GCNT2 | c.925+27149A>T | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- GHDC | c.1289-33G>T | Intron (SNP) | VAF 12/113 reads (11%) | catalogued as COSV53187323; called by mutect2, varscan2
- GLYATL1 | c.-166-241T>A | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- KDM5C | c.229-297G>T | Intron (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MBNL3 | c.1053+783T>C | Intron (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- MSRB3 | c.98-18211G>T | Intron (SNP) | VAF 43/351 reads (12%) | called by muse, mutect2, varscan2
- MUC2 | c.*25C>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- OR2P1P | chr6:29076425 C>G | 5'Flank (SNP) | VAF 16/131 reads (12%) | catalogued as rs1487733486; called by muse, mutect2, varscan2
- OR56B3P | n.758C>A | RNA (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- OR9Q1 | c.-15+53217G>T | Intron (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- PEX5L | c.94-2432C>A | Intron (SNP) | VAF 29/217 reads (13%) | called by muse, mutect2, varscan2
- RPL30 | c.299-318A>G | Intron (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2, varscan2
- SHISA6 | c.799+115888G>T | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, varscan2
- SHOC2 | c.-235+17329G>T | Intron (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- SLC37A4 | c.785-21C>T | Intron (SNP) | VAF 6/93 reads (6%) | catalogued as rs1373081038; called by muse, mutect2
- SLC6A10P | n.2934G>A | RNA (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- SNORD114-23 | chr14:100983834 C>A | 5'Flank (SNP) | VAF 8/56 reads (14%) | called by muse, varscan2
- SNX29 | c.1402+9095del | Intron (DEL) | VAF 10/78 reads (13%) | catalogued as rs1567195470; called by mutect2, pindel, varscan2
- TBC1D15 | c.-31G>T | 5'UTR (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- TGFBR3 | c.*2029A>G | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- TMEM187 | c.*17G>T | 3'UTR (SNP) | VAF 26/192 reads (14%) | called by muse, mutect2, varscan2
- TPCN2 | c.*7G>T | 3'UTR (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2811-22175A>T | Intron (SNP) | VAF 40/194 reads (21%) | called by muse, varscan2
- UBXN4 | c.83-587G>T | Intron (SNP) | VAF 12/121 reads (10%) | catalogued as rs1334256147; called by muse, mutect2
- UGT3A1 | c.94+16G>A | Intron (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- VEPH1 | c.138+6020G>T | Intron (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75516094 C>A | 5'Flank (SNP) | VAF 22/190 reads (12%) | called by muse, mutect2, varscan2
- ZNF449 | c.354+17G>T | Intron (SNP) | VAF 22/333 reads (7%) | called by muse, mutect2
- ZNF879 | c.34-20G>T | Intron (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2
